Somatic mutation profile of tumor specimen TCGA-64-5815-01A (aliquot TCGA-64-5815-01A-01D-1625-08) from TCGA case TCGA-64-5815, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.7 years (27,280 days).
Specimen TCGA-64-5815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 782952ed-acef-475f-b35c-79f1a393c370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5815-10A (Blood Derived Normal), aliquot TCGA-64-5815-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc0056c0-4e36-45ed-9c78-20aa0a0dba7b

The open-access MAF lists 188 somatic variants for this specimen: 142 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 42, Nonsense Mutation 14, Frame Shift Del 5, Splice Site 3, Splice Region 2, RNA 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as COSV55664824; called by mutect2, varscan2
- ADGRG7 | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as COSV56299491; called by muse, mutect2, varscan2
- ANO7 | c.1528G>T p.V510L (on ENST00000274979; = p.V456L on NM_001370694.2) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.215); catalogued as COSV51475842; called by muse, mutect2, varscan2
- AOAH | c.1368C>A p.V456= | Splice Region (SNP) | VAF 20/84 reads (24%) | catalogued as COSV51747125; called by muse, mutect2, varscan2
- APOH | c.936T>A p.D312E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV52773889; called by muse, mutect2, varscan2
- ARID4A | c.1320A>T p.L440F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV62165542; called by muse, mutect2, varscan2
- ATP1A2 | c.2484C>G p.I828M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63405058; called by muse, mutect2, varscan2
- AVEN | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs758534979, COSV100145874; called by muse, mutect2, varscan2
- B3GNT6 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100845810; called by muse, mutect2
- BCHE | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52260061; called by muse, mutect2, varscan2
- BRDT | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as COSV62866364; called by muse, mutect2, varscan2
- C10orf90 | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1411413409, COSV52960241; called by muse, mutect2, varscan2
- C1orf141 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as COSV100924395; called by muse, mutect2, varscan2
- CACNA2D1 | c.3278G>A p.W1093* (on ENST00000356253 / NM_001366867.1; = p.W1081* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV62387139; called by muse, mutect2, varscan2
- CADM2 | c.535C>A p.R179S (on ENST00000407528 / NM_001167674.2; = p.R181S on NM_153184.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs759648918, COSV101059551, COSV67359574; called by mutect2, varscan2
- CASQ2 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54772652; called by muse, mutect2, varscan2
- CASR | c.1197G>C p.E399D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV56138657; called by muse, mutect2, varscan2
- CASS4 | c.1347C>A p.H449Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100824928; called by muse, mutect2, varscan2
- CER1 | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101097930; called by muse, mutect2, varscan2
- CNTNAP2 | c.2891C>A p.S964* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100673007; called by muse, mutect2, varscan2
- COL19A1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775237157, COSV59580956, COSV59581289; called by muse, mutect2, varscan2
- COL21A1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372065490; called by muse, mutect2, varscan2
- COL7A1 | c.8107C>A p.R2703= | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as COSV56476966; called by muse, mutect2, varscan2
- CPZ | c.1500G>T p.E500D (on ENST00000360986 / NM_001014447.3; = p.E489D on NM_003652.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59924570; called by muse, mutect2, varscan2
- CRYBA4 | c.75del p.R26Gfs*22 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | catalogued as COSV61322096; called by mutect2, pindel, varscan2
- CSMD3 | c.10850C>A p.S3617* (on ENST00000297405 / NM_001363185.1; = p.S3448* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV52260847, COSV99830282; called by muse, mutect2, varscan2
- CYTH3 | c.369-2A>T p.X123_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV63440287; called by muse, mutect2
- DCAF7 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60408313; called by muse, mutect2, varscan2
- DDX11 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs758984389, COSV52504307; called by muse, mutect2, varscan2
- DENND2D | c.1060A>T p.I354F | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV62959716; called by muse, mutect2, varscan2
- DHX38 | c.2507G>T p.G836V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51699784; called by muse, mutect2, varscan2
- DLG1 | c.2316T>A p.D772E (on ENST00000419354 / NM_001290983.1; = p.D794E on NM_004087.2) | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV58387912; called by muse, mutect2, varscan2
- DLL1 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.133); catalogued as COSV100816095, COSV64538129; called by muse, mutect2, varscan2
- DNER | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100520089, COSV59174681; called by muse, mutect2, varscan2
- DRICH1 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as COSV58504439; called by muse, mutect2, varscan2
- DSG1 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1427235253, COSV57137909; called by mutect2, varscan2
- DUOX2 | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV66533394; called by muse, mutect2, varscan2
- EIF2AK4 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55472018; called by muse, mutect2, varscan2
- EPHB6 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67420093; called by muse, mutect2, varscan2
- ERBB2 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99509147; called by muse, mutect2, varscan2
- FAAH | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs970642010, COSV54545219; called by muse, mutect2, varscan2
- FIG4 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57789738; called by muse, mutect2, varscan2
- FLNC | c.3487C>A p.P1163T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57961039; called by muse, mutect2, varscan2
- FMN2 | c.2416A>T p.S806C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV60443606; called by muse, mutect2, varscan2
- FOXD4L3 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs1554670948, COSV100731036; called by muse, mutect2, varscan2
- GCC1 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99133956; called by muse, mutect2, varscan2
- GFPT2 | c.1518G>T p.E506D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1432515030, COSV53810894; called by muse, mutect2, varscan2
- GLIPR1 | c.211T>A p.W71R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56992054; called by muse, mutect2, varscan2
- GNAZ | c.530G>C p.R177P | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99321215; called by muse, mutect2, varscan2
- GPR20 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100897425; called by muse, mutect2, varscan2
- GRIN3A | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62456574; called by muse, mutect2, varscan2
- HIPK3 | c.3059C>T p.P1020L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV57564446; called by muse, mutect2, varscan2
- IGSF10 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56789459; called by muse, mutect2, varscan2
- ISM2 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); catalogued as rs748631666, COSV53636199; called by muse, mutect2, varscan2
- JAG2 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV59311433; called by muse, mutect2
- KCNK10 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773338019, COSV56649528; called by muse, mutect2, varscan2
- KDM8 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs145879289; called by muse, mutect2, varscan2
- KLHL4 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64145835; called by muse, mutect2, varscan2
- KRI1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV57265404; called by muse, mutect2, varscan2
- LILRB2 | c.1550T>A p.L517Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV58747304; called by muse, mutect2, varscan2
- LIN52 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV63246934; called by muse, mutect2
- MAP3K7 | c.1076A>C p.Q359P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.091); catalogued as COSV65225406; called by muse, varscan2
- MAT1A | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64746551; called by muse, mutect2, varscan2
- MDC1 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs372848423, COSV64526160; called by muse, mutect2, varscan2
- MEIS2 | c.1392T>A p.D464E | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.215); catalogued as COSV54941611; called by muse, mutect2, varscan2
- MMP20 | c.1163C>A p.P388Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52777136; called by muse, mutect2, varscan2
- MTMR12 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 26/196 reads (13%) | catalogued as COSV53786373; called by muse, mutect2, varscan2
- MTUS2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV70919022; called by muse, mutect2
- NLRP9 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1201633109, COSV60466067; called by muse, mutect2, varscan2
- NPAP1 | c.2044G>T p.V682L | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV61509580; called by muse, mutect2, varscan2
- NPLOC4 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100481228; called by muse, mutect2
- NTS | c.302T>A p.M101K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99755209; called by muse, mutect2, varscan2
- OR2AK2 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV63557880; called by muse, mutect2, varscan2
- OR4B1 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs377574489, COSV100535580; called by muse, mutect2, varscan2
- OR5B2 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56909153; called by muse, mutect2, varscan2
- OR7E24 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV101509671, COSV71702222; called by muse, mutect2, varscan2
- OTOGL | c.6722C>T p.T2241I (on ENST00000547103; = p.T2232I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54018771, COSV54020667; called by muse, mutect2, varscan2
- PALD1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV54976861; called by muse, mutect2, varscan2
- PAPPA2 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.331); catalogued as COSV62782985; called by muse, mutect2, varscan2
- PCDHGA1 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV65294949, COSV65298277; called by muse, mutect2, varscan2
- PCNT | c.95C>G p.S32W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV52450998; called by muse, mutect2, varscan2
- POLQ | c.4432G>T p.V1478F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV51757803; called by muse, mutect2, varscan2
- POMT1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs777486298, COSV61227152; called by muse, mutect2, varscan2
- PPDPF | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100925649; called by muse, mutect2, varscan2
- PPIP5K2 | c.3074G>T p.S1025I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58606932, COSV58608104; called by muse, mutect2, varscan2
- PRKAG3 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52103076; called by muse, mutect2, varscan2
- PTK7 | c.3090G>T p.E1030D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV57850347; called by muse, mutect2, varscan2
- PTPN14 | c.113C>G p.S38W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65286395; called by muse, mutect2, varscan2
- RBM46 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99908427; called by muse, mutect2, varscan2
- RIMS2 | c.2288G>C p.R763T (on ENST00000666250 / NM_001348490.2; = p.R571T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705425; called by muse, mutect2, varscan2
- RIMS4 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs199825737, COSV65720331; called by muse, mutect2, varscan2
- RP1 | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV55122458; called by muse, mutect2, varscan2
- RTCB | c.1507A>T p.I503F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53279790; called by muse, mutect2, varscan2
- SATB2 | c.476G>T p.C159F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.791); catalogued as COSV53489747; called by muse, mutect2, varscan2
- SCCPDH | c.1185-2A>G p.X395_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV63619026; called by muse, mutect2
- SCN4A | c.5365T>A p.S1789T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71128055; called by muse, mutect2, varscan2
- SEMA5A | c.2701G>T p.E901* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101228166; called by muse, mutect2
- SEMG1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.47); catalogued as COSV54873894; called by muse, mutect2, varscan2
- SENP5 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV100052282; called by muse, mutect2, varscan2
- SETD9 | c.804C>G p.D268E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV53650870; called by muse, mutect2, varscan2
- SEZ6L | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV50673927; called by mutect2, varscan2
- SEZ6L | c.2324C>A p.P775H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50673958; called by muse, mutect2, varscan2
- SHROOM3 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV56035871; called by muse, mutect2, varscan2
- SLC17A3 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100399413, COSV57760327; called by muse, mutect2, varscan2
- SLC1A3 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54318741; called by muse, mutect2, varscan2
- SORCS3 | c.3409G>C p.G1137R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63818657; called by muse, mutect2
- SPATA16 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs764534706, COSV63526159, COSV63531673; called by muse, mutect2, varscan2
- SRCAP | c.7133C>T p.T2378I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760969953, COSV52677769; called by muse, mutect2
- SUPT5H | c.2087G>T p.R696M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV100782158; called by muse, mutect2, varscan2
- TEX14 | c.1452C>A p.Y484* (on ENST00000240361 / NM_001201457.2; = p.Y478* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53622637; called by muse, mutect2, varscan2
- TEX15 | c.3541G>T p.D1181Y (on ENST00000256246; = p.D1564Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56350472; called by muse, mutect2, varscan2
- TIAM1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739051; called by muse, mutect2
- TMTC4 | c.1624G>T p.A542S (on ENST00000376234 / NM_001350577.2; = p.A561S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60893155; called by muse, mutect2, varscan2
- TNR | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV54888216, COSV54902787; called by muse, mutect2, varscan2
- TNXB | c.5038G>A p.G1680R (on ENST00000647633; = p.G1433R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs755953436, COSV64484856; called by muse, mutect2, varscan2
- TRAV18 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs1404787326; called by muse, mutect2, varscan2
- TRPC6 | c.1990C>A p.Q664K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.634); catalogued as COSV100723765; called by muse, mutect2, varscan2
- TSHZ3 | c.2697C>A p.N899K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV53677932, COSV99552016; called by muse, mutect2, varscan2
- TTC24 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758366523, COSV63998184; called by muse, mutect2, varscan2
- TTC5 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs774819158, COSV51871778; called by muse, mutect2, varscan2
- UBE2V2 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV72879120, COSV72879283; called by muse, mutect2
- UGT2B10 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55319656, COSV55322299; called by muse, mutect2, varscan2
- VEGFC | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54596751, COSV54603187; called by muse, mutect2, varscan2
- VPS13D | c.5526C>G p.H1842Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV50662142; called by muse, mutect2, varscan2
- VWF | c.2037C>A p.C679* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99780183; called by muse, mutect2, varscan2
- WWC1 | c.2617G>T p.E873* | Nonsense Mutation (SNP) | VAF 64/158 reads (41%) | catalogued as COSV54655558; called by muse, mutect2, varscan2
- XIRP2 | c.3859G>T p.D1287Y (on ENST00000628543; = p.D1462Y on NM_152381.6) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54682299, COSV99747528; called by mutect2, varscan2
- ZCCHC13 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100272592; called by muse, mutect2
- ZEB2 | c.1685del p.L562* | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as CM013800; called by mutect2, pindel, varscan2
- ZFHX4 | c.2118C>A p.Y706* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99267782; called by muse, mutect2, varscan2
- ZFP57 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65306655; called by muse, mutect2, varscan2
- ZFP64 | c.1195A>T p.K399* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV99403055; called by muse, mutect2, varscan2
- ZIC4 | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV67170582, COSV67173271; called by muse, mutect2, varscan2
- ZNF253 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63038063; called by muse, mutect2, varscan2
- ZNF479 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV58641712; called by muse, mutect2, varscan2
- ZNF786 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV100303017; called by muse, mutect2, varscan2
- CACNA1F | c.5429_5430del p.R1810Pfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- KIR3DL1 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KIZ | c.1272_1274del p.T425del | In Frame Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel
- SSU72P8 | c.284del p.P95Qfs*42 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by pindel, varscan2
- TRIM72 | c.770del p.P257Hfs*28 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel
- ABCA13 | c.9024C>T p.S3008= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as rs757980942, COSV71292188; called by muse, mutect2, varscan2
- ABCD3 | c.324A>T p.T108= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV59867231; called by muse, mutect2
- ACP4 | c.1036C>T p.L346= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as rs200838416, COSV54518069; called by muse, mutect2, varscan2
- ACTC1 | c.918T>A p.T306= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as rs397517074, COSV51760436; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQP12B | c.252G>T p.V84= (on ENST00000621682; = p.V96= on NM_001102467.2) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs758564498, COSV68184271; called by muse, mutect2, varscan2
- AQP2 | c.522T>A p.L174= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99550950; called by muse, mutect2
- ASB15 | c.891A>T p.P297= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV51928132; called by muse, mutect2, varscan2
- ATP13A1 | c.1365C>T p.A455= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99366613; called by mutect2, varscan2
- BCL11A | c.507C>T p.H169= (on ENST00000335712 / NM_001365609.1; = p.H203= on NM_018014.4) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1405736110, COSV59624224, COSV59624844; called by muse, mutect2, varscan2
- C10orf90 | c.429G>A p.T143= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs377010024; called by muse, mutect2, varscan2
- CARD6 | c.2010C>T p.S670= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV54566312; called by muse, mutect2, varscan2
- CELF5 | c.387C>T p.R129= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs762908282, COSV53013694; called by muse, mutect2, varscan2
- CLCN3 | c.540A>T p.T180= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV61628028; called by muse, mutect2, varscan2
- DOLPP1 | c.273A>T p.T91= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV59910782; called by muse, mutect2, varscan2
- EEFSEC | c.1323G>A p.T441= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs143447496; called by muse, mutect2, varscan2
- EML2 | c.951G>T p.R317= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV55602231; called by muse, mutect2, varscan2
- F13A1 | c.1242G>T p.S414= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99343955; called by muse, mutect2, varscan2
- F8 | c.2952G>A p.S984= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs782148632, COSV64276824; called by muse, mutect2, varscan2
- FURIN | c.2199C>T p.F733= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV51578526; called by muse, mutect2, varscan2
- GFOD2 | c.39C>T p.G13= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV52059225; called by muse, mutect2, varscan2
- GPR4 | c.600G>T p.S200= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100547213; called by muse, mutect2, varscan2
- HDAC2 | c.1464C>T p.P488= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1416138953, COSV64039002; called by muse, mutect2, varscan2
- HECW2 | c.282T>G p.L94= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV53668656; called by muse, mutect2, varscan2
- IMPG2 | c.2925C>T p.V975= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV51982813; called by muse, mutect2, varscan2
- INPP5D | c.87C>A p.L29= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV64038985; called by muse, mutect2, varscan2
- KRT74 | c.933C>A p.I311= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs776156648, COSV59771041, COSV59772824; called by muse, mutect2, varscan2
- MAGEB18 | c.96G>T p.V32= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100305632; called by muse, mutect2, varscan2
- MSH6 | c.3720A>G p.K1240= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs786203260, COSV52284540; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.1332C>A p.T444= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as COSV67969692; called by muse, mutect2, varscan2
- NAIF1 | c.897C>T p.Y299= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs1041966694, COSV66091857; called by muse, mutect2, varscan2
- OR1S2 | c.849T>A p.T283= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV56920026; called by muse, mutect2, varscan2
- OR2L13 | c.357C>T p.Y119= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs1438157332, COSV63553802; called by muse, mutect2, varscan2
- OR5F1 | c.579C>A p.I193= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1317772323, COSV53545369, COSV53547790; called by muse, mutect2, varscan2
- OR7E24 | c.153C>A p.S51= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1193060188, COSV101509688, COSV71702121; called by muse, mutect2, varscan2
- PPBP | c.384T>C p.D128= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99933047; called by muse, mutect2, varscan2
- PRPSAP1 | c.765A>T p.P255= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV61212174; called by muse, mutect2, varscan2
- RINL | c.1566C>T p.S522= (on ENST00000591812 / NM_001195833.2; = p.S408= on NM_198445.4) | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV61575296; called by muse, mutect2, varscan2
- RNF19A | c.1464T>G p.A488= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV61994222; called by muse, mutect2, varscan2
- RXRG | c.288C>A p.P96= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100717873; called by muse, mutect2
- SORCS1 | c.595C>T p.L199= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53864413, COSV53889346; called by muse, mutect2, varscan2
- THSD7A | c.1416C>T p.N472= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV70269424; called by muse, mutect2, varscan2
- ZNF536 | c.1779C>T p.D593= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV62830102; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445748 G>A | 3'Flank (SNP) | VAF 12/79 reads (15%) | catalogued as rs143442078; called by muse, mutect2, varscan2
- MAGEA5 | n.143G>T | RNA (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- MIR1303 | n.60del | RNA (DEL) | VAF 33/72 reads (46%) | called by mutect2, pindel*, varscan2
- VKORC1 | chr16:31095517 T>C | 5'Flank (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100161858; called by muse, mutect2
